Gene-level copy-number profile of tumor specimen TCGA-AR-A2LL-01A from TCGA case TCGA-AR-A2LL, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 70.5 years (25,747 days).
Specimen TCGA-AR-A2LL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.1e086721-663c-47b9-9753-a468d2b1df1b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A2LL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6ad79639-f5e6-4680-aac1-96e48c483f34

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 5,915; copy number 3: 4,760; copy number 4: 21,102; copy number 5: 17,469; copy number 6: 3,380; copy number 7: 731; copy number 8: 10; copy number 9: 4,533; copy number 11: 251; copy number 12: 13; copy number 13: 8; copy number 14: 1,534; copy number 16: 1; copy number 17: 9; copy number 20: 29; copy number 22: 1; copy number 30: 12; copy number 33: 32; copy number 34: 20; copy number 39: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AR-A2LL-01): tumor purity 0.71, ploidy 2.18, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 6,444 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 9–11 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 14 (broad region; genes not listed).
- chr9:68,328,308–70,354,873, 36 genes, copy number 13–39: PGM5, PGM5-AS1, AL161457.2, AL161457.1, TMEM252, TMEM252-DT, LINC01506, AL353616.1, PIP5K1B, FAM122A, AL354794.2, AL354794.1, RNU6-820P, PRKACG, AL358113.1, FXN, AL162730.1, TJP2, BANCR, FAM189A2, APBA1, AL355140.1, AL353693.1, AL162412.1, PTAR1, C9orf135-DT, C9orf135, RN7SL570P, MAMDC2-AS1, MAMDC2, RNU2-5P, SMC5-AS1, RPL24P8, SMC5, AL162390.1, Y_RNA.
- chr10:15,237,492–15,241,767, 1 gene, copy number 22: AL607028.1.
- chr10:34,926,775–35,231,394, 13 genes, copy number 12: RNU6-847P, RNU6-193P, PRDX2P2, LINC02635, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P.
- chr10:36,089,086–36,089,389, 1 gene, copy number 16: AL355300.1.
- chr10:37,125,725–37,384,111, 1 gene, copy number 20 (within-gene range 8–20): ANKRD30A.
- chr10:37,240,887–37,544,701, 7 genes, copy number 20: AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P, TACC1P1.
- chr10:38,094,334–38,783,108, 21 genes, copy number 20: ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1.
- chr10:78,943,328–79,677,996, 18 genes, copy number 34: ZMIZ1-AS1, AL356753.1, ZMIZ1, PPIF, ZCCHC24, AL133481.1, TPRX1P1, AL133481.3, AL133481.2, EIF5AL1, BX248123.1, RPS12P18, SFTPA2, MBL3P, SFTPA3P, SFTPA1, LINC02679, AL132656.2.
- chr10:79,663,192–79,684,094, 2 genes, copy number 34: AL132656.3, AL132656.4.
- chr10:126,393,489–127,452,517, 9 genes, copy number 17: AL589787.2, LINC00601, C10orf90, AL589787.1, AL512272.1, DOCK1, AL359094.1, AL359094.2, INSYN2A.
- chr10:132,332,154–133,226,412, 17 genes, copy number 33 (within-gene range 2–33): LRRC27, PWWP2B, AL451069.2, AL451069.3, LINC02870, AL451069.1, LINC01165, INPP5A, NKX6-2, CFAP46, LINC01166, LINC01167, LINC01168, ADGRA1, ADGRA1-AS1, RPL5P28, KNDC1.
- chr17:19,203,825–58,747,340, 1,486 genes, copy number 9 (broad region; genes not listed).
- chr17:58,785,323–58,835,994, 2 genes, copy number 9: Metazoa_SRP, RNU6-518P.
- chr17:62,319,884–83,095,122, 692 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
